Gene-level copy-number profile of tumor specimen TCGA-55-7283-01A from TCGA case TCGA-55-7283, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.5 years (27,946 days).
Specimen TCGA-55-7283-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e697f67d-09da-4575-a856-c39e26ad70f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7283-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab1dc1a2-f15f-493b-a3b5-bd8d313baa63

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,538; copy number 3: 21,741; copy number 4: 18,655; copy number 5: 1,837; copy number 6: 10,095; copy number 7: 1,237; copy number 8: 2,717.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7283-01A-11D-2035-01): tumor purity 0.47, ploidy 3.9, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,954 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,040,233–45,750,653, 209 genes, copy number 7 (broad region; genes not listed).
- chr1:56,154,545–56,524,495, 2 genes, copy number 7 (within-gene range 3–7): AC119674.1, AC119674.2.
- chr1:56,414,935–56,918,223, 9 genes, copy number 7: LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A.
- chr1:56,994,778–58,546,734, 9 genes, copy number 7 (within-gene range 3–7): DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 8 (broad region; genes not listed).
- chr2:207,821,288–212,538,841, 55 genes, copy number 7 (within-gene range 4–7): PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1, PTH2R, ARPC1BP1, H3P9, AC019185.1, AC019185.2, AC109824.1, RNA5SP117, HSPA8P6, CRYGFP, MEAF6P1, PKP4P1, AC016743.1, MAP2, RNA5SP118, UNC80, SNAI1P1, RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1, AC012491.1, RPS27P10, ERBB4, RNA5SP119, MTND2P23, MTCO1P46, MIR548F2.
- chr4:54,657,918–55,161,880, 10 genes, copy number 7: KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2.
- chr6:29,212,886–61,241,311, 897 genes, copy number 7 (broad region; genes not listed).
- chr10:26,931,206–28,623,112, 39 genes, copy number 8: FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC.
- chr10:31,693,084–33,917,804, 41 genes, copy number 8: MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.
- chr10:34,201,979–34,202,074, 1 gene, copy number 8: Y_RNA.
- chr12:66,767–911,452, 23 genes, copy number 8 (within-gene range 2–8): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1.
- chr12:17,479,446–18,648,416, 9 genes, copy number 8 (within-gene range 2–8): AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1.
- chr12:24,642,687–26,421,462, 44 genes, copy number 7: AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 7: AC055720.2, RNA5SP354.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
